Somatic mutation profile of tumor specimen TCGA-14-1829-01A (aliquot TCGA-14-1829-01A-01D-1494-08) from TCGA case TCGA-14-1829, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.3 years (20,929 days).
Specimen TCGA-14-1829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6650e63-e294-49bb-9fe3-7ce5fb67c02b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1829-10A (Blood Derived Normal), aliquot TCGA-14-1829-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8820161-b06d-4cdc-8622-c3a7fcab6449

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 33, Silent 14, Splice Region 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.12104G>T p.G4035V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV67987883; called by muse, mutect2, varscan2
- AKR1B10 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1562928667, COSV62055800; called by muse, mutect2, varscan2
- CEP152 | c.1174-1G>A p.X392_splice | Splice Site (SNP) | VAF 31/81 reads (38%) | catalogued as COSV57860632; called by muse, mutect2, varscan2
- DPPA4 | c.912A>C p.E304D | Missense Mutation (SNP) | VAF 138/535 reads (26%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV59511048; called by muse, mutect2
- EBF2 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.382); catalogued as COSV68778693; called by muse, mutect2, varscan2
- ETF1 | c.864A>G p.G288= | Splice Region (SNP) | VAF 71/162 reads (44%) | catalogued as rs776841173, COSV62127596; called by muse, mutect2, varscan2
- EXOSC10 | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58666002; called by muse, mutect2, varscan2
- GFRAL | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61232039; called by muse, mutect2
- GPR37 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs754836352, COSV58257537; called by muse, mutect2, varscan2
- KMT2B | c.2080C>T p.R694W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs372982681; called by muse, mutect2, varscan2
- LY96 | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV53025729; called by muse, mutect2, varscan2
- MAN2B1 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV55472810; called by muse, mutect2, varscan2
- METRNL | c.265C>A p.L89I | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.814); catalogued as COSV60760803; called by muse, varscan2
- METRNL | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.998); catalogued as COSV60760819; called by muse, varscan2
- MUC16 | c.36742C>T p.R12248C | Missense Mutation (SNP) | VAF 99/378 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.276); catalogued as rs753950558, COSV67468660; called by muse, mutect2, varscan2
- MUC16 | c.6352G>A p.A2118T | Missense Mutation (SNP) | VAF 85/409 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs749152513, COSV67455691; called by muse, mutect2, varscan2
- NLRP12 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs777735292, COSV60749384; called by muse, mutect2, varscan2
- NRXN3 | c.1744G>A p.A582T (on ENST00000557594 / NM_001272020.2; = p.A1006T on NM_004796.6) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55333949; called by muse, mutect2, varscan2
- OR10J3 | c.656A>T p.Y219F | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59954796; called by muse, mutect2
- OR4D10 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs761012920, COSV73260081; called by muse, mutect2, varscan2
- PCDH11X | c.1103T>A p.V368D | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100010634; called by muse, varscan2
- PCDHB6 | c.1148T>C p.I383T | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as rs142117819; called by muse, mutect2, varscan2
- PCDHB7 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as rs544763939, COSV50754257; called by muse, mutect2, varscan2
- PKD2 | c.1564A>G p.I522V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs374402854, COSV52939096; called by muse, mutect2
- RAB3GAP2 | c.2875G>T p.A959S | Missense Mutation (SNP) | VAF 166/486 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.033); catalogued as COSV62783668, COSV62784945; called by muse, mutect2, varscan2
- SLC17A8 | c.1391G>A p.C464Y | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60124615; called by muse, mutect2, varscan2
- SMG1 | c.6272G>A p.R2091H | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1198488974, COSV67171045; called by muse, mutect2
- SPEG | c.8014G>A p.V2672M | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs773412903, COSV56671717; called by muse, mutect2, varscan2
- TAF2 | c.293C>G p.S98* | Nonsense Mutation (SNP) | VAF 35/338 reads (10%) | catalogued as COSV65418740; called by muse, mutect2, varscan2
- TCHH | c.4865G>A p.R1622H | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV100914884, COSV64275588; called by muse, mutect2, varscan2
- TPSAB1 | c.666C>T p.G222= | Splice Region (SNP) | VAF 9/35 reads (26%) | catalogued as rs566260324, COSV100126944; called by muse, mutect2, varscan2
- TREML1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs1158030899, COSV58294929; called by muse, mutect2, varscan2
- U2SURP | c.1183A>G p.N395D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.199); catalogued as COSV67531584; called by muse, mutect2, varscan2
- URGCP | c.1939C>A p.P647T (on ENST00000453200 / NM_001077663.3; = p.P638T on NM_017920.4) | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56249012; called by muse, mutect2, varscan2
- URGCP | c.1028C>G p.S343C (on ENST00000453200 / NM_001077663.3; = p.S334C on NM_017920.4) | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56249032; called by muse, mutect2, varscan2
- URGCP | c.294C>G p.I98M (on ENST00000453200 / NM_001077663.3; = p.I89M on NM_017920.4) | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56249050; called by muse, mutect2, varscan2
- USP42 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV60361280; called by muse, mutect2, varscan2
- HHIPL2 | c.351C>T p.Y117= | Silent (SNP) | VAF 110/280 reads (39%) | catalogued as rs1291388394, COSV58563595; called by muse, mutect2, varscan2
- IL12RB1 | c.1785G>T p.G595= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV74045553; called by muse, mutect2
- KLHDC8A | c.126C>T p.N42= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs1222917574, COSV65678959; called by muse, mutect2, varscan2
- LTBR | c.781C>T p.L261= | Silent (SNP) | VAF 66/141 reads (47%) | catalogued as COSV57439165; called by muse, mutect2, varscan2
- NUP133 | c.1932C>T p.A644= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs374819603, COSV54572485; called by muse, mutect2, varscan2
- PIK3CG | c.120C>T p.I40= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs1004936166, COSV63249566; called by muse, mutect2, varscan2
- RTP5 | c.378C>T p.Y126= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs771455989, COSV58320558; called by muse, mutect2, varscan2
- SIAH3 | c.294C>T p.H98= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs773723798, COSV68552240; called by muse, mutect2, varscan2
- SLIT2 | c.2160T>C p.S720= | Silent (SNP) | VAF 170/509 reads (33%) | catalogued as COSV56577313; called by muse, mutect2, varscan2
- TLL2 | c.1377G>A p.A459= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs750004312, COSV63573275; called by muse, mutect2, varscan2
- TRIM4 | c.369C>T p.I123= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs746597075, COSV57209766, COSV57210449; called by muse, mutect2, varscan2
- TRIM62 | c.252C>G p.L84= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV52221941; called by muse, mutect2, varscan2
- UBIAD1 | c.414C>G p.L138= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as COSV65147856; called by muse, mutect2, varscan2
- URGCP | c.2025C>G p.V675= (on ENST00000453200 / NM_001077663.3; = p.V666= on NM_017920.4) | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV56248988; called by muse, mutect2, varscan2
